TCGA case TCGA-FD-A3B6 — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: BLN - University Of Chicago. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/36054200-3fa4-4541-a25c-47282e4ef88d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 75 years; Vital status: Dead; Days to death: 1,005 days (2.8 years).

Diagnoses (3)
1. Papillary transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8130/3; ICD-10 code: C67.4; Tissue or organ of origin: Posterior wall of bladder; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 75.4 years (27,541 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC pathologic T: T2b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Days to last follow up: 1,005 days (2.8 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 15.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Prostate gland; Laterality: Bilateral; Classification of tumor: Synchronous primary; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: MX.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Carcinoma, NOS: Tissue or organ of origin: Prostate gland; Classification of tumor: Synchronous primary; AJCC pathologic T: T2c.

Follow-up (2 entries)
- Days to follow up: 209 days; Disease response: Tumor Free.
- Follow-up contact recording only the day: day 1,005.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 72.57 kg; Height: 172.72 cm; BMI: 24.3.

Exposures
- Occupation type: Domestic, Hotel and Office Cleaners and Helpers.
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 60; Age at onset: 17.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FD-A3B6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 470 mg.
  Slide TCGA-FD-A3B6-01A-02-TSB: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 25; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FD-A3B6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FD-A3B6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Occupation current: retired; Occupation primary: janitor; Tobacco smoking history indicator: 2; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Papillary; Anatomic organ subdivision: Wall Posterior; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Incidental prostate cancer indicator: Yes; AJCC path pathologic T incidental prostate: pT2c.
- Stage record, Gleason grading: Gleason score: 6.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Prostate; Other malignancy laterality: Both; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: 37.

GDC annotations on this case (curator notes; quoted as recorded):
- Synchronous malignancy: Patient had synchronous prostate cancer. No radiation or systemic chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,005 days; disease-specific survival: no event (censored), 1,005 days; disease-free interval: no event (censored), 1,005 days; progression-free interval: no event (censored), 1,005 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FD-A3B6-01A-21D-A20B-01): tumor purity 0.42, ploidy 3.21, whole-genome doublings 1.
